Somatic mutation profile of tumor specimen BA2855D (aliquot aq-BA2855D) from BEATAML1.0 case 2085, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with t(8;21)(q22;q22), RUNX1-RUNX1T1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.7 years (18,512 days).
Specimen BA2855D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4974625a-8a45-4187-89d3-1e7d0e3d65e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2462D (Solid Tissue Normal), aliquot aq-BA2462D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1b0f3e2-e2b6-49f3-b6f7-9f540ff8f615

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYTIP | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs538136043; called by mutect2, varscan2
- DNMT3A | c.2477A>T p.K826M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV53083630; called by mutect2, varscan2
- EVC2 | c.2153G>A p.G718D | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1256824226; called by muse, mutect2
- MYO6 | c.2840G>A p.R947Q | Missense Mutation (SNP) | VAF 56/503 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs377681616; called by muse, mutect2, varscan2
- NCAPG2 | c.596del p.D199Vfs*17 | Frame Shift Del (DEL) | VAF 21/238 reads (9%) | called by mutect2, pindel
- KCNH4 | c.2235G>T p.L745= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- RADIL | c.3171C>T p.V1057= | Silent (SNP) | VAF 23/254 reads (9%) | catalogued as rs773741937, COSV68202771; called by muse, mutect2, varscan2
